Somatic mutation profile of tumor specimen 0DCBJ3 from CCDI case PBBMGD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 14.4 years (5,264 days).
Specimen 0DCBJ3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b3eafa3-5c83-4b0e-9557-0013e63663af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCBIW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eaef35e-a97b-4ffa-981a-34c32a19a6b6

The open-access MAF lists 112 somatic variants for this specimen: 76 protein-altering or splice-affecting, 15 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 15, 3'UTR 9, Intron 5, 5'UTR 5, Nonsense Mutation 4, Splice Region 2, 5'Flank 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 148/365 reads (41%) | catalogued as rs587783509, COSV52119548; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 374/964 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.3193C>G p.R1065G | Missense Mutation (SNP) | VAF 248/727 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52481019, COSV99322995; called by muse, mutect2, varscan2
- CD200R1L | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 128/382 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142953807, COSV68004161; called by muse, mutect2, varscan2
- CDH10 | c.1043T>A p.V348D | Missense Mutation (SNP) | VAF 542/1035 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52586796; called by muse, mutect2, varscan2
- CUL9 | c.3934C>T p.R1312C | Missense Mutation (SNP) | VAF 227/605 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs772547986, COSV99335827; called by muse, mutect2, varscan2
- DLGAP4 | c.2926G>A p.E976K (on ENST00000339266 / NM_001365621.1; = p.E973K on NM_014902.6) | Missense Mutation (SNP) | VAF 237/959 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs573801205; called by muse, mutect2, varscan2
- DNAH7 | c.4451C>G p.T1484R | Missense Mutation (SNP) | VAF 279/978 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100413720; called by muse, mutect2, varscan2
- EZR | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 310/777 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1309244595; called by muse, mutect2, varscan2
- GALNT11 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 283/1151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756592916, COSV57425100; called by muse, mutect2, varscan2
- GLIS3 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 162/489 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs751567499, COSV67946718; called by muse, mutect2, varscan2
- ISYNA1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99526399; called by muse, mutect2, varscan2
- LDOC1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 149/425 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV65159284; called by muse, mutect2, varscan2
- OR8H3 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 433/1839 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57907407; called by muse, mutect2, varscan2
- OSGEPL1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 154/609 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs762966073, COSV51462787; called by muse, mutect2, varscan2
- PDGFA | c.404C>G p.T135R | Missense Mutation (SNP) | VAF 168/581 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779400956, COSV100627292, COSV63279803; called by muse, mutect2, varscan2
- PHACTR1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 236/675 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs759309026, COSV60682570; called by muse, mutect2, varscan2
- PLEC | c.12655G>A p.D4219N (on ENST00000322810 / NM_201380.4; = p.D4109N on NM_000445.5) | Missense Mutation (SNP) | VAF 150/952 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201221940, COSV59698538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNB3 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 265/787 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.281); catalogued as rs782347144; called by muse, mutect2, varscan2
- PNPLA1 | c.1235C>A p.A412D (on ENST00000394571 / NM_001374623.1; = p.A317D on NM_173676.2) | Missense Mutation (SNP) | VAF 132/446 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs919843591; called by muse, mutect2, varscan2
- RIMKLB | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 173/965 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as rs754185655; called by muse, mutect2, varscan2
- SI | c.5079T>A p.C1693* | Nonsense Mutation (SNP) | VAF 225/607 reads (37%) | catalogued as COSV52275200; called by muse, mutect2, varscan2
- SIAE | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 207/1243 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1458453304; called by muse, mutect2, varscan2
- SLC22A17 | n.1665G>A | Splice Region (SNP) | VAF 135/362 reads (37%) | catalogued as COSV52836131; called by muse, mutect2, varscan2
- SLC38A9 | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 226/448 reads (50%) | catalogued as COSV100591280; called by muse, mutect2
- SPRED1 | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 22/670 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as CM093927, COSV100136330; called by muse, mutect2
- SPTA1 | c.4759G>C p.E1587Q | Missense Mutation (SNP) | VAF 210/608 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV63749725; called by muse, mutect2, varscan2
- TAPBP | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 115/335 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs770421374; called by muse, mutect2, varscan2
- TMEM259 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs142318806, COSV99312413; called by muse, mutect2, varscan2
- TRGC1 | c.158C>G p.T53R | Missense Mutation (SNP) | VAF 222/866 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs563835813; called by muse, mutect2, varscan2
- ZHX2 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 169/1100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768362732, COSV58714812, COSV58716649; called by muse, mutect2, varscan2
- ZSWIM5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 261/759 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as rs374367203; called by muse, mutect2, varscan2
- AFM | c.1059-1G>T p.X353_splice | Splice Site (SNP) | VAF 87/278 reads (31%) | called by muse, mutect2, varscan2
- ALG5 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 322/939 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCN5 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 165/376 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CLK4 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 214/1066 reads (20%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CNTN1 | c.1423A>T p.T475S | Missense Mutation (SNP) | VAF 157/759 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DPYSL5 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 268/803 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- DSCAM | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 196/513 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- DYNC2H1 | c.2531A>T p.E844V | Missense Mutation (SNP) | VAF 173/953 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- EIF2S2 | c.329C>G p.P110R | Missense Mutation (SNP) | VAF 232/926 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2S3 | c.199G>C p.V67L | Missense Mutation (SNP) | VAF 28/962 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2
- ENOX2 | c.439G>C p.V147L (on ENST00000338144 / NM_001382520.1; = p.V118L on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 229/738 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FGFR4 | c.1057+3_1057+6dup | Splice Region (INS) | VAF 530/3467 reads (15%) | called by mutect2, varscan2
- FGFR4 | c.1536_1538dup p.K512_D513insE | In Frame Ins (INS) | VAF 1534/2023 reads (76%) | called by mutect2, varscan2
- HEPH | c.1742T>C p.L581P (on ENST00000343002; = p.L314P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/537 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPCL1 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 374/764 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IBTK | c.3118C>G p.P1040A | Missense Mutation (SNP) | VAF 170/506 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LGALS3BP | c.1163T>A p.F388Y | Missense Mutation (SNP) | VAF 180/485 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- LMOD2 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 221/707 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- MAGEL2 | c.3332G>T p.G1111V | Missense Mutation (SNP) | VAF 245/699 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MS4A10 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 243/895 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MUC16 | c.29324G>T p.S9775I | Missense Mutation (SNP) | VAF 46/592 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2
- MYRIP | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 167/477 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NECTIN2 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NKX2-4 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- OR1L8 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 376/1072 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR2G3 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 263/958 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by mutect2, varscan2
- PFKFB1 | c.8C>A p.P3Q | Missense Mutation (SNP) | VAF 212/663 reads (32%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF20L1 | c.1765A>C p.S589R | Missense Mutation (SNP) | VAF 306/1879 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PLS3 | c.1088C>G p.P363R | Missense Mutation (SNP) | VAF 274/701 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PLXNA3 | c.5126C>A p.P1709H | Missense Mutation (SNP) | VAF 179/510 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- R3HCC1L | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 165/382 reads (43%) | called by muse, mutect2, varscan2
- RCOR2 | c.1143G>C p.E381D | Missense Mutation (SNP) | VAF 169/502 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- RMND1 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 202/637 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RSBN1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 126/294 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- RTEL1 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 174/661 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SCARF2 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- SERPINA9 | c.845T>A p.L282Q | Missense Mutation (SNP) | VAF 117/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC6A14 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 207/576 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TCP11L1 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 183/1089 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRIM42 | c.482G>T p.C161F | Missense Mutation (SNP) | VAF 145/402 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM6 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 231/868 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- UBL4A | c.288G>C p.W96C | Missense Mutation (SNP) | VAF 144/408 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- YTHDF3 | c.523A>G p.N175D | Missense Mutation (SNP) | VAF 228/1330 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFAT | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 166/1126 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CDCP1 | c.2346G>A p.R782= | Silent (SNP) | VAF 82/197 reads (42%) | called by muse, mutect2, varscan2
- CYP4Z1 | c.861A>T p.I287= | Silent (SNP) | VAF 226/684 reads (33%) | called by muse, mutect2, varscan2
- DNAH5 | c.10347C>A p.A3449= | Silent (SNP) | VAF 539/1082 reads (50%) | called by muse, mutect2, varscan2
- GOLM1 | c.699C>T p.S233= | Silent (SNP) | VAF 321/873 reads (37%) | called by muse, mutect2, varscan2
- H3C4 | c.177C>A p.T59= | Silent (SNP) | VAF 174/463 reads (38%) | called by muse, mutect2, varscan2
- IGSF9B | c.243C>T p.H81= | Silent (SNP) | VAF 126/570 reads (22%) | catalogued as rs372311737; called by muse, mutect2, varscan2
- LRPPRC | c.3537C>T p.F1179= | Silent (SNP) | VAF 56/653 reads (9%) | called by muse, mutect2
- MCC | c.1011C>T p.S337= | Silent (SNP) | VAF 514/937 reads (55%) | catalogued as rs780358275; called by muse, mutect2, varscan2
- NWD2 | c.4053A>G p.E1351= | Silent (SNP) | VAF 210/566 reads (37%) | called by muse, mutect2, varscan2
- PDZRN4 | c.1722C>T p.A574= (on ENST00000402685 / NM_001164595.2; = p.A316= on NM_013377.4) | Silent (SNP) | VAF 179/743 reads (24%) | catalogued as rs775182732; called by muse, mutect2, varscan2
- RABEP2 | c.1251G>T p.L417= | Silent (SNP) | VAF 167/513 reads (33%) | called by muse, mutect2, varscan2
- SEL1L | c.990G>C p.S330= | Silent (SNP) | VAF 90/269 reads (33%) | catalogued as COSV60921349; called by muse, mutect2, varscan2
- SMURF1 | c.123C>T p.V41= | Silent (SNP) | VAF 314/1204 reads (26%) | catalogued as rs764180314; called by muse, mutect2, varscan2
- SVEP1 | c.9996A>G p.E3332= | Silent (SNP) | VAF 214/606 reads (35%) | called by muse, mutect2, varscan2
- ZNF875 | c.933G>C p.T311= | Silent (SNP) | VAF 54/610 reads (9%) | catalogued as rs555011193, COSV60991034; called by muse, mutect2
- ARMC6 | c.-19G>A | 5'UTR (SNP) | VAF 106/287 reads (37%) | catalogued as rs775909415; called by muse, mutect2, varscan2
- ARPC1A | c.*70C>T | 3'UTR (SNP) | VAF 118/426 reads (28%) | catalogued as rs1489958993, COSV99501084; called by muse, mutect2, varscan2
- ATM | c.5762+1024G>A | Intron (SNP) | VAF 146/943 reads (15%) | called by muse, mutect2, varscan2
- BCKDK | c.717-68C>A | Intron (SNP) | VAF 58/146 reads (40%) | called by muse, varscan2
- C6orf118 | c.1303-58A>T | Intron (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- CCSER2 | c.*294G>C | 3'UTR (SNP) | VAF 230/603 reads (38%) | catalogued as COSV99825596; called by muse, mutect2, varscan2
- CD274 | c.*33G>A | 3'UTR (SNP) | VAF 146/389 reads (38%) | catalogued as rs1227393361; called by muse, mutect2, varscan2
- KAT8 | c.*88G>T | 3'UTR (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- LRRCC1 | chr8:85107217 C>A | 5'Flank (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- OR10J1 | c.*10A>G | 3'UTR (SNP) | VAF 124/377 reads (33%) | called by muse, mutect2, varscan2
- PDE2A | c.-75G>T | 5'UTR (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- POU4F1 | c.-64C>G | 5'UTR (SNP) | VAF 40/140 reads (29%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.*2T>C | 3'UTR (SNP) | VAF 139/371 reads (37%) | called by muse, mutect2, varscan2
- RNPC3 | c.1208-99T>G | Intron (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- ROBO3 | c.2846+57C>G | Intron (SNP) | VAF 93/453 reads (21%) | called by muse, mutect2, varscan2
- SIAH1 | c.*91C>T | 3'UTR (SNP) | VAF 165/483 reads (34%) | catalogued as rs753782001; called by muse, mutect2, varscan2
- STX2 | c.-39C>T | 5'UTR (SNP) | VAF 78/226 reads (35%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*1C>T | 3'UTR (SNP) | VAF 161/612 reads (26%) | catalogued as rs772530865, COSV70501931; called by muse, mutect2, varscan2
- TMEM181 | c.-11G>C | 5'UTR (SNP) | VAF 135/345 reads (39%) | called by muse, mutect2, varscan2
- TRAPPC9 | chr8:140458517 C>G | 5'Flank (SNP) | VAF 165/1044 reads (16%) | catalogued as rs1019866616; called by muse, mutect2, varscan2
- ZNF844 | c.*37C>A | 3'UTR (SNP) | VAF 58/136 reads (43%) | called by mutect2, varscan2
